Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAE7, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAE7-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: Hepatocellular carcinoma suggested

Specimen : Liver and Liver mass

Gross Photo :

GROSS:

Specimen status: Fresh

Operation: Partial hepatectomy

Organs: Liver (10.0 x 9.0 x 2.5 cm, 155.5 gm)

Lesion: A well-defined pale yellow to tan solid and firm mass (3.3 x 2.0 x 2.8 cm)

Cut surface: Yellowish tan, and solid without necrosis

Gross type:

HCC: Vaguely nodular

Resection margin: Not involved grossly (safety margin: 1.5 cm)

Others:

Satellite nodule: No

Remaining parenchyma: Steatosis, mild

Representative sections submitted

Gross photo: Present

Blocks

TB, T1-4, tumor mass x 5

L, NB, liver parenchyma x 2

RM, resection margin x 1

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

Q2 5/20/14

MICROSCOPIC:

Hepatocellular carcinoma: Yes

The worst differentiation II

The major differentiation II

Histologic type: Trabecular

Cell type: Hepatic

Fatty change: Yes (5%)

Fibrous capsule formation: No

Septum formation: No

Surgical resection margin invasion: No, safety margin (1.5 cm)

Serosal invasion: No

Portal vein invasion: No

Microvessel invasion: No

Intrahepatic metastasis: Unknown

Multicentric occurrence: Unknown

NOT reported. Gross:

NOT reported. Gross:

[page 2 of 2]
Stomach, antrum, dissection, adenocarcinoma, arising in, tubular adenoma

liver, ectomy, Hepatocellular carcinoma, well differentiated, steatosis
T56000, P10, M81703, well differentiated, M50080

DIAGNOSIS:

Liver, segment 5-8, partial hepatectomy:

Hepatocellular carcinoma, well differentiated

Steatosis, mild

Suggestion :

Source: NCI Genomic Data Commons file a7df6534-b203-4329-a9bc-2d74ada31d2c (TCGA-DD-AAE7.1861F2A9-334D-4C4E-A7D0-D010712D6096.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).